Somatic mutation profile of tumor specimen C3L-05315-54 (aliquot CPT0340590002) from CPTAC case C3L-05315, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 52.2 years (19,073 days).
Specimen C3L-05315-54: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e2713050-c0ae-472f-ad62-4d3ccfc93e19.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-05315-50 (Buccal Cell Normal), aliquot CPT0340560004; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1521a1a5-5e43-47f4-b760-363b7ef6fdf2

The open-access MAF lists 1 somatic variant for this specimen: 1 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGAP39 | c.2356_2372delinsTTTTTTAATGATCCGCC p.I786_Q791delinsFFNDPP | Missense Mutation (ONP) | VAF 8/97 reads (8%) | called by mutect2*, pindel
